Gene-level copy-number profile of specimen HCM-BROD-0043-C16-85B from HCMI case HCM-BROD-0043-C16, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 68.7 years (25,092 days).
Specimen HCM-BROD-0043-C16-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Mixed Adherent Suspension; Preservation method: Frozen; Passage count: 7.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 316efc71-3971-4035-90c6-b6ed39ccbece.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0043-C16-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,723 have no estimate.
https://portal.gdc.cancer.gov/files/e1bfb709-a380-4a8a-9578-a64d6fc011a8

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 931; copy number 2: 6,774; copy number 3: 21,050; copy number 4: 15,444; copy number 5: 7,556; copy number 6: 4,265; copy number 7: 2,262; copy number 8: 310; copy number 9: 90; copy number 10: 92; copy number 11: 27; copy number 12: 26; copy number 13: 13; copy number 14: 4; copy number 15: 20; copy number 16: 20; copy number 17: 4; copy number 18: 5; copy number 19: 1; copy number 24: 2; copy number 29: 4.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,880 genes in 37 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:61,561,569–69,968,336, 86 genes, copy number 7–29 (broad region; genes not listed).
- chr3:70,125,070–70,140,488, 2 genes, copy number 7: AC139700.1, UQCRHP4.
- chr3:138,187,248–140,867,783, 48 genes, copy number 7–11: ARMC8, NME9, MRAS, ESYT3, AC022497.1, CEP70, FAIM, PPIAP72, PIK3CB, GAPDHP39, RPL23AP40, EEF1A1P25, ATP5MC1P3, LINC01391, FOXL2, FOXL2NB, PRR23A, MRPS22, PRR23B, PRR23C, RPL7L1P7, BPESC1, PISRT1, AC119740.1, AC024933.2, AC024933.1, COPB2, U6, AC046134.2, RBP2, AC097103.1, ACTG1P1, RBP1, NMNAT3, AC046134.1, RN7SKP124, RN7SL724P, AC110716.2, AC110716.1, AC016933.1, TRMT112P5, CLSTN2, AC010181.1, AC010181.2, CLSTN2-AS1, AC048346.1, TRIM42, AC121333.1.
- chr3:164,171,471–164,831,480, 3 genes, copy number 7: MIR1263, LINC01323, LINC01324.
- chr3:168,858,659–198,123,232, 579 genes, copy number 7 (broad region; genes not listed).
- chr4:54,009,789–54,064,605, 2 genes, copy number 10 (within-gene range 6–10): CHIC2, AC110792.2.
- chr4:54,229,280–54,740,715, 6 genes, copy number 10–11 (within-gene range 6–11): PDGFRA, LINC02283, AC098587.1, AC098868.1, LINC02260, KIT.
- chr4:71,741,696–71,804,041, 2 genes, copy number 7: GC, RNA5SP163.
- chr4:72,323,028–72,330,751, 1 gene, copy number 7 (within-gene range 6–7): AC095056.1.
- chr4:73,710,302–73,778,060, 3 genes, copy number 8: UMLILO, CXCL8, AC112518.1.
- chr4:167,946,674–168,537,786, 6 genes, copy number 8–9 (within-gene range 4–9): AC116634.1, ANXA10, AC068989.1, DDX60, DDX60L, AC079926.1.
- chr4:173,419,245–175,019,214, 25 genes, copy number 7–12: RPL5P11, RNU6-1096P, AC093849.1, HAND2, HAND2-AS1, MORF4, RANP6, LINC02269, AC106895.1, AC106895.2, LINC02268, AC012055.1, AC012055.2, FBXO8, CEP44, AC116616.1, MIR4276, HPGD, AC096751.2, AC096751.1, GLRA3, ADAM29, AC105914.1, AC105914.2, AC022325.1.
- chr5:58,198–2,119,926, 74 genes, copy number 8 (broad region; genes not listed).
- chr6:24,797,373–48,068,689, 946 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr7:13,854,355–20,415,754, 76 genes, copy number 7–8 (broad region; genes not listed).
- chr7:66,070,904–66,094,697, 2 genes, copy number 7 (within-gene range 6–7): AC068533.1, ASL.
- chr7:66,407,288–67,362,950, 40 genes, copy number 7 (within-gene range 6–7): GTF2IP9, SKP1P1, AC008267.2, AC008267.4, AC008267.7, AC008267.5, AC008267.6, GS1-124K5.4, AC008267.1, AC008267.3, AC006001.3, AC006001.4, SAPCD2P3, AC006001.1, RPL35P5, KCTD7, AC027644.4, AC006001.2, RABGEF1, AC027644.3, AC027644.2, GTF2IRD1P1, AC027644.1, GTF2IP23, RNU6-1254P, LINC02604, AC073335.1, Metazoa_SRP, TMEM248, RN7SL43P, SBDS, TYW1, AC073089.1, MIR4650-1, SPDYE21, PMS2P4, Y_RNA, STAG3L4, AC006480.1, AC006480.2.
- chr7:71,779,491–76,919,191, 153 genes, copy number 7 (broad region; genes not listed).
- chr7:76,968,197–77,004,308, 3 genes, copy number 7 (within-gene range 6–7): FDPSP7, AC114737.1, DTX2P1.
- chr7:77,122,434–77,329,533, 1 gene, copy number 7 (within-gene range 6–7): CCDC146.
- chr7:77,246,340–93,911,265, 174 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr7:93,885,396–93,890,753, 1 gene, copy number 7 (within-gene range 6–7): TFPI2.
- chr7:94,695,027–101,629,296, 221 genes, copy number 7 (broad region; genes not listed).
- chr7:102,327,256–102,434,780, 9 genes, copy number 7 (within-gene range 6–7): AC091390.1, Y_RNA, PMS2P12, SPDYE6, PRKRIP1, AC091390.3, AC091390.2, MIR548O, AC073517.1.
- chr7:103,161,947–104,208,047, 14 genes, copy number 7: AC007683.3, DPY19L2P2, S100A11P1, PMPCB, DNAJC2, PSMC2, RPS29P16, SLC26A5, Y_RNA, Y_RNA, AC005064.1, RELN, RN7SKP86, ORC5.
- chr10:31,602,862–35,572,669, 64 genes, copy number 7–8 (broad region; genes not listed).
- chr10:61,901,684–62,919,900, 12 genes, copy number 7–8 (within-gene range 5–8): ARID5B, RTKN2, LINC02621, AC024597.1, RN7SL591P, ZNF365, AC024598.1, AC067752.1, AC067751.1, ALDH7A1P4, ADO, EGR2.
- chr10:66,926,036–67,101,551, 2 genes, copy number 10 (within-gene range 5–10): LRRTM3, AL139240.1.
- chr10:74,151,202–76,560,168, 35 genes, copy number 7–15 (within-gene range 6–15): ADK, TIMM9P1, RPSAP6, RAB5CP1, AC022540.1, MRPL35P3, Y_RNA, NDUFA8P1, POLR3DP1, FAM32CP, AC063962.1, KAT6B, AC018511.2, AC018511.1, DUSP29, AC018511.6, PPIAP13, DUSP13, SAMD8, RPS26P42, VDAC2, COMTD1, ZNF503-AS1, RPL39P25, HMGA1P5, AC010997.3, AC010997.1, SPA17P1, ZNF503, ZNF503-AS2, AC010997.5, AC010997.4, AC010997.2, LRMDA, AC010997.6.
- chr10:75,592,644–76,836,861, 10 genes, copy number 8–9: AL589863.2, AL589863.1, AL731568.1, RN7SL518P, RNU6-673P, AC012048.1, AC013286.1, AC024603.1, AC013738.1, ATP5MC1P8.
- chr10:78,696,062–80,653,732, 63 genes, copy number 8–19 (broad region; genes not listed).
- chr10:80,776,165–81,137,335, 3 genes, copy number 7: FARSBP1, WARS2P1, RPA2P2.
- chr12:67,424,272–67,442,559, 2 genes, copy number 7: NTAN1P3, LINC02420.
- chr13:72,703,693–72,706,123, 2 genes, copy number 7: RPL21P110, RNU6-80P.
- chr14:35,511,825–49,913,760, 179 genes, copy number 8–12 (broad region; genes not listed).
- chr15:84,467,901–84,526,949, 6 genes, copy number 7–11 (within-gene range 4–11): Metazoa_SRP, UBE2Q2P12, AC048382.4, AC048382.3, GOLGA6L5P, AC048382.2.
- chr18:21,704,957–22,419,294, 25 genes, copy number 7–10: MIB1, AC106037.1, Y_RNA, RN7SL233P, SNORA73, MIR133A1HG, MIR133A1, MIR1-2, AC103987.1, AC103987.2, RNU6-1038P, AC103987.3, RNA5SP451, LINC01900, AC091043.1, RNU6ATAC20P, GATA6-AS1, GATA6, AC091588.1, RNU6-702P, AC091588.3, AC091588.2, AC027449.1, CTAGE1, ATP7BP1.

Autosomal genes at a single copy (total copy number 1): 931. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
